CCDI case PBBMHS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/aa4b2c57-b32a-4e5a-97dc-6d6881ea0100

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.7 years (6,084 days).

Biospecimens (3 samples)
- Sample 0DDHSF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDHSI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDHSJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
